Somatic mutation profile of tumor specimen TCGA-C5-A7UH-01A (aliquot TCGA-C5-A7UH-01A-11D-A351-09) from TCGA case TCGA-C5-A7UH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.3 years (20,189 days).
Specimen TCGA-C5-A7UH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 581032e4-46f7-4291-a672-12d76faf42e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7UH-10A (Blood Derived Normal), aliquot TCGA-C5-A7UH-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e44b7d3c-dad6-4707-8fff-327fb86d2302

The open-access MAF lists 225 somatic variants for this specimen: 175 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 47, Nonsense Mutation 16, Frame Shift Del 5, Frame Shift Ins 1, RNA 1, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 45/85 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- ADAMTS12 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs768132388, COSV61271725; called by muse, mutect2, varscan2
- ADD3 | c.521T>A p.I174K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370426959, COSV53324503; called by muse, mutect2, varscan2
- ADGRB3 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV65409683; called by mutect2, varscan2
- ADGRV1 | c.1259T>G p.V420G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67991302; called by muse, mutect2, varscan2
- AKAP13 | c.8170G>A p.E2724K (on ENST00000394518 / NM_007200.5; = p.E2728K on NM_006738.6) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV63465120; called by muse, mutect2, varscan2
- ALDOB | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs371526091, COSV66398334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX12 | c.1471G>T p.G491W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV52351026; called by muse, mutect2, varscan2
- AMER1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100366174, COSV57664474; called by muse, mutect2, varscan2
- ANKS1A | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV64462786; called by muse, mutect2, varscan2
- ATF6B | c.1892C>G p.S631* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV64352313; called by muse, mutect2, varscan2
- ATP8B4 | c.771G>T p.Q257H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52720564; called by muse, mutect2, varscan2
- BAZ1B | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV59992955; called by muse, mutect2, varscan2
- BRINP3 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66533534; called by muse, mutect2, varscan2
- BTAF1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV56437071, COSV56439368; called by muse, mutect2, varscan2
- C1orf131 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs531305779, COSV59642807; called by muse, mutect2, varscan2
- CC2D1B | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1184158913, COSV52561798; called by muse, mutect2, varscan2
- CCDC14 | c.445G>A p.E149K (on ENST00000488653; = p.E101K on NM_022757.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59946558; called by muse, mutect2, varscan2
- CCDC77 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs776322698, COSV53473976, COSV53474422; called by muse, mutect2
- CCHCR1 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1278307071, COSV66184553; called by muse, mutect2, varscan2
- CD2BP2 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777916992, COSV59769353; called by muse, mutect2, varscan2
- CD34 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777117210, COSV60412407; called by muse, mutect2, varscan2
- CD58 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV65665184; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4927T>C p.S1643P | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62576627; called by muse, mutect2, varscan2
- CELSR2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs1395065293, COSV54771298; called by muse, mutect2
- CFAP47 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.059); catalogued as COSV52888943, COSV52889482; called by muse, mutect2
- CGNL1 | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748553704, COSV55572131, COSV99848120; called by muse, mutect2, varscan2
- CHD4 | c.1909G>A p.D637N (on ENST00000357008 / NM_001363606.2; = p.D650N on NM_001273.5) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58907124; called by muse, mutect2, varscan2
- CHMP6 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV57327775, COSV57328386; called by muse, mutect2, varscan2
- CIRBP | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58011762; called by muse, mutect2, varscan2
- CLIP3 | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53325352; called by muse, mutect2, varscan2
- CUBN | c.6850G>A p.D2284N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as COSV64722549; called by muse, mutect2, varscan2
- CYP2A6 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV56536360; called by muse, mutect2, varscan2
- DACH1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as rs1330298263, COSV57512070; called by muse, mutect2, varscan2
- DAPP1 | c.306G>C p.L102F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV56452567; called by muse, mutect2, varscan2
- DDR1 | c.2707C>T p.R903W (on ENST00000324771; = p.R866W on NM_001954.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); catalogued as rs766893592, COSV61323278; called by mutect2, varscan2
- DENND10 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV63858002; called by muse, mutect2, varscan2
- DISP2 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV51132278; called by muse, mutect2, varscan2
- DNMBP | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs780955774, COSV60629983; called by muse, mutect2, varscan2
- DUOX1 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as COSV58484522; called by muse, mutect2, varscan2
- DYM | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.897); catalogued as COSV53989184; called by muse, mutect2, varscan2
- DYNC1I1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV61466983; called by muse, mutect2, varscan2
- EFCAB6 | c.3441G>C p.E1147D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53068407; called by muse, mutect2, varscan2
- EFHC1 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs534406651, COSV64137151; called by muse, mutect2, varscan2
- ELL | c.990C>A p.F330L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV99443504; called by muse, mutect2, varscan2
- ELN | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV52713149; called by muse, mutect2, varscan2
- EP300 | c.3709G>T p.D1237Y | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54339717; called by muse, varscan2
- EP300 | c.4934G>A p.R1645Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV54332029; called by muse, mutect2, varscan2
- EPHB3 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV57807849; called by mutect2, varscan2
- EPRS1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV65100416; called by muse, mutect2, varscan2
- F10 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65022525; called by muse, mutect2, varscan2
- FAM172A | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101232708, COSV67939021; called by muse, mutect2, varscan2
- FBXW4 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs769937106, COSV58709052; called by muse, mutect2, varscan2
- FCGBP | c.7843G>A p.E2615K | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1199326769, COSV55447005; called by muse, mutect2, varscan2
- FMN1 | c.2510C>A p.S837Y (on ENST00000616417 / NM_001277313.2; = p.S614Y on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV57919464, COSV57928946; called by muse, mutect2, varscan2
- FOXA3 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.185); catalogued as COSV56216996; called by muse, mutect2, varscan2
- GALNT17 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61178090; called by muse, mutect2, varscan2
- GALNT6 | c.1329C>A p.F443L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV62542827; called by muse, mutect2, varscan2
- GAP43 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59343013; called by muse, mutect2, varscan2
- GCM1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52522435; called by muse, mutect2, varscan2
- GDA | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1027052641, COSV52995971; called by muse, mutect2, varscan2
- GFRA2 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV60780671; called by muse, mutect2, varscan2
- GNA11 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.339); catalogued as COSV50023608; called by muse, mutect2, varscan2
- GPAA1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100284034, COSV60156237; called by muse, mutect2, varscan2
- GPAA1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV60156243; called by muse, mutect2, varscan2
- H2BC5 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.134); catalogued as COSV56802702; called by muse, mutect2, varscan2
- HECTD1 | c.4797G>T p.L1599F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV67948170; called by muse, mutect2, varscan2
- HECTD3 | c.1872G>A p.W624* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV64670563; called by muse, mutect2, varscan2
- HNRNPA0 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV59246818; called by muse, mutect2, varscan2
- HPS5 | c.1246C>G p.Q416E (on ENST00000349215 / NM_181507.2; = p.Q302E on NM_007216.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV61687785; called by muse, mutect2, varscan2
- HRH1 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101229100, COSV67955777; called by muse, mutect2, varscan2
- HTR1B | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV64051728; called by muse, mutect2, varscan2
- HTR3D | c.727C>G p.L243V (on ENST00000382489 / NM_001163646.2; = p.L70V on NM_182537.3) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61915018; called by muse, mutect2, varscan2
- HTR4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140360260; called by muse, mutect2, varscan2
- IFNGR1 | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV62989414, COSV62990148, COSV62990505; called by muse, mutect2, varscan2
- INO80 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV62740730; called by muse, mutect2, varscan2
- INPP5D | c.3233T>C p.V1078A (on ENST00000445964 / NM_001017915.3; = p.V1077A on NM_005541.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV64038917; called by muse, mutect2
- ITGA4 | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52001410, COSV52002465, COSV52003753; called by muse, mutect2, varscan2
- JMJD6 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as rs1283219231, COSV57974239; called by muse, mutect2, varscan2
- KAT2A | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56792054; called by muse, mutect2, varscan2
- KCNV1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1000789197, COSV52085311, COSV52087728; called by muse, mutect2, varscan2
- KIF20B | c.5444G>A p.R1815Q (on ENST00000371728 / NM_001284259.2; = p.R1775Q on NM_016195.4) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53303158, COSV53311184; called by muse, mutect2, varscan2
- KMT2B | c.5897C>T p.S1966F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as rs201138169; called by muse, mutect2, varscan2
- KMT2C | c.7615C>T p.Q2539* | Nonsense Mutation (SNP) | VAF 42/52 reads (81%) | catalogued as COSV51452659; called by muse, mutect2, varscan2
- LAMC1 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.533); catalogued as COSV51157824; called by muse, mutect2, varscan2
- LDHC | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV55005257; called by muse, mutect2, varscan2
- LRFN1 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50483180; called by muse, mutect2
- LRRC37A3 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV59763014; called by muse, mutect2, varscan2
- LZTR1 | c.1074C>G p.F358L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV53149768; called by muse, mutect2, varscan2
- MAGEE1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1556839448, COSV63911320; called by muse, mutect2, varscan2
- MAMDC2 | c.506-1G>A p.X169_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV65859602; called by muse, mutect2, varscan2
- MAP3K19 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs923551681, COSV59640885; called by muse, mutect2, varscan2
- MAPKAP1 | c.1405G>A p.E469K (on ENST00000265960 / NM_001006617.3; = p.E433K on NM_024117.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56371942; called by muse, mutect2, varscan2
- MATN2 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV54716177; called by muse, mutect2, varscan2
- MBOAT1 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV61126780; called by muse, mutect2, varscan2
- MCF2 | c.2157C>G p.F719L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV58490839; called by muse, mutect2, varscan2
- MED26 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV54661870, COSV54662422; called by mutect2, varscan2
- MUC16 | c.41548G>C p.E13850Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs547030245, COSV66694946; called by muse, mutect2, varscan2
- MZF1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV53041462; called by muse, mutect2, varscan2
- NOL6 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV53044363; called by mutect2, varscan2
- NPAS4 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV60651806; called by muse, mutect2, varscan2
- NPEPPS | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV59104232; called by muse, mutect2, varscan2
- NPEPPS | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59104239; called by muse, mutect2, varscan2
- NRG4 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67530746; called by muse, mutect2, varscan2
- NSD1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV61780541, COSV61786914; called by muse, varscan2
- NSD1 | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV61780547; called by muse, varscan2
- NSD1 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV61780557; called by muse, mutect2, varscan2
- NUP133 | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1456749725, COSV99773199; called by muse, mutect2, varscan2
- PCDHGA9 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.208); catalogued as COSV53995845; called by muse, mutect2, varscan2
- PCDHGA9 | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV53995860; called by muse, mutect2, varscan2
- PCNX3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV58420976; called by muse, mutect2, varscan2
- PDLIM2 | c.698G>A p.R233Q (on ENST00000397760; = p.R483Q on NM_021630.6) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs779427808, COSV56134145; called by muse, mutect2, varscan2
- PLEKHA6 | c.2030G>A p.R677K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV55337718; called by muse, mutect2
- PPP4R4 | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV58556745; called by muse, mutect2, varscan2
- PRL | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as rs148157654; called by muse, mutect2, varscan2
- PRRC2B | c.949A>T p.R317* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV61940891; called by muse, mutect2, varscan2
- PSG5 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.068); catalogued as COSV61654826; called by muse, mutect2
- PTPRS | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.643); catalogued as COSV53630058; called by muse, mutect2, varscan2
- PXDC1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66661879; called by muse, mutect2, varscan2
- PYHIN1 | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV63723297; called by muse, mutect2, varscan2
- RALGPS1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs755182642, COSV52228181; called by muse, mutect2, varscan2
- RALYL | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV72823635; called by muse, mutect2, varscan2
- RBFOX1 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV60970486; called by muse, mutect2, varscan2
- RBM12 | c.1453A>C p.K485Q | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as COSV58293563; called by muse, mutect2, varscan2
- RBM14 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.885); catalogued as rs773352601, COSV59559661; called by muse, mutect2, varscan2
- RBM14 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV59560078; called by muse, mutect2, varscan2
- RUSC1 | c.321C>G p.S107R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV52741621; called by muse, mutect2
- RUSC1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs1010038488, COSV52738572, COSV52741625; called by muse, mutect2
- RUSC2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63429673; called by muse, mutect2, varscan2
- SAMD1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs770299017, COSV54116198; called by muse, mutect2, varscan2
- SERGEF | c.1025C>G p.S342* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV56385960; called by muse, mutect2, varscan2
- SH3RF2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs747678660, COSV100767903; called by muse, mutect2, varscan2
- SMARCA4 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60789026, COSV60803586; called by muse, mutect2, varscan2
- SMARCA4 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1555763975, COSV60788923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG1 | c.8260C>A p.H2754N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV67173660, COSV67173742; called by muse, mutect2, varscan2
- SORCS1 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53862509, COSV53888722; called by muse, mutect2, varscan2
- SRPK2 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV61963042; called by muse, mutect2, varscan2
- STON2 | c.755C>T p.S252L (on ENST00000649389 / NM_001366849.2; = p.S195L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as rs1249112534, COSV50849357; called by mutect2, varscan2
- SYNPO2 | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61114664; called by muse, mutect2
- SYTL2 | c.1721G>A p.R574K (on ENST00000528231 / NM_001162951.2; = p.R1863K on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV60361528; called by muse, mutect2, varscan2
- TBC1D19 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs377374054; called by muse, mutect2, varscan2
- TBC1D2B | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs759507296, COSV56044692; called by muse, mutect2, varscan2
- TBCK | c.586G>C p.E196Q (on ENST00000273980 / NM_001163436.4; = p.E133Q on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV56759691; called by muse, mutect2, varscan2
- TBX18 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV63737579, COSV63738274; called by muse, mutect2, varscan2
- TCF25 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54531185; called by muse, mutect2, varscan2
- TLE2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53581877; called by muse, mutect2, varscan2
- TLN1 | c.4615C>G p.L1539V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs151033435; called by muse, mutect2, varscan2
- TMEM135 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as COSV59704030; called by muse, mutect2, varscan2
- TMEM41B | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs775632699, COSV55156185; called by muse, mutect2, varscan2
- TNS2 | c.2830G>A p.E944K (on ENST00000314250 / NM_170754.4; = p.E954K on NM_015319.2) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as rs151178618; called by muse, mutect2, varscan2
- TP53TG5 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV54782251; called by muse, mutect2, varscan2
- TRIM39 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV64956057; called by muse, mutect2, varscan2
- TTN | c.59080G>C p.E19694Q (on ENST00000591111; = p.E12270Q on NM_003319.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | PolyPhen probably damaging (0.997); catalogued as COSV60221006; called by muse, mutect2, varscan2
- TTN | c.52819C>T p.L17607F (on ENST00000591111; = p.L10183F on NM_003319.4) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | PolyPhen probably damaging (0.999); catalogued as COSV60221046; called by muse, mutect2, varscan2
- USH2A | c.6976G>C p.E2326Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100233513, COSV56406248; called by muse, mutect2, varscan2
- USO1 | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.228); catalogued as rs1440541230, COSV53706315; called by muse, mutect2, varscan2
- USP29 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54144788; called by muse, mutect2, varscan2
- USP29 | c.1420G>C p.D474H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54144791; called by muse, mutect2, varscan2
- USP34 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs746117870, COSV67658804; called by muse, mutect2, varscan2
- ZBED4 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs780126311, COSV53466947; called by muse, mutect2, varscan2
- ZBTB6 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771237203, COSV65410425; called by muse, mutect2, varscan2
- ZCCHC8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV60319231; called by muse, mutect2, varscan2
- ZFAT | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV64735347; called by muse, mutect2, varscan2
- ZNF157 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV65659184, COSV65659364; called by muse, mutect2, varscan2
- ZNF433 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV61399908; called by muse, mutect2, varscan2
- ZNF594 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV68385882; called by muse, mutect2, varscan2
- ZNF790 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs746439754, COSV63212949; called by muse, mutect2, varscan2
- EP300 | c.3701del p.R1234Kfs*43 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | called by pindel, varscan2
- KIDINS220 | c.1305_1306dup p.D436Vfs*45 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- LAT | c.789_*1del | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- PARM1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RDM1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SOCS3 | c.347_354del p.R116Lfs*24 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- TDRD1 | c.46del p.E16Kfs*7 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel*, varscan2
- UNC5B | c.161del p.P54Hfs*7 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ADCY7 | c.2202G>A p.S734= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs752983838, COSV54269222; called by muse, mutect2, varscan2
- ANKRD52 | c.1938C>T p.I646= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV57285163, COSV57286132; called by muse, mutect2, varscan2
- APPL2 | c.927C>T p.L309= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs955847740, COSV51592336; called by muse, mutect2, varscan2
- ARF5 | c.24C>G p.L8= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV50001701; called by muse, mutect2, varscan2
- BTBD1 | c.177C>T p.F59= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1239018598, COSV55603972, COSV55603979; called by muse, mutect2
- CCZ1B | c.132G>A p.K44= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV57438641; called by mutect2, varscan2
- CDC123 | c.291C>T p.L97= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs763125813, COSV55398971; called by muse, mutect2, varscan2
- COL5A2 | c.3921G>A p.Q1307= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV66412427; called by muse, mutect2, varscan2
- CPM | c.1065C>G p.L355= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100615189; called by muse, mutect2, varscan2
- CPNE7 | c.1545G>A p.L515= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99254979; called by muse, mutect2
- FBXW8 | c.414C>T p.Y138= (on ENST00000309909; = p.Y176= on NM_012174.1) | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs376292994; called by muse, mutect2, varscan2
- FEM1B | c.1299C>T p.V433= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1325758966, COSV60989158; called by muse, mutect2, varscan2
- FFAR3 | c.279C>T p.F93= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV59909426; called by muse, mutect2, varscan2
- GLIPR1 | c.84C>T p.I28= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs775097349, COSV56990230, COSV56991321; called by muse, mutect2, varscan2
- GPR39 | c.282C>T p.I94= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV61426219; called by muse, mutect2, varscan2
- HELZ2 | c.1917G>A p.A639= (on ENST00000467148 / NM_001037335.2; = p.A70= on NM_033405.3) | Silent (SNP) | VAF 38/55 reads (69%) | catalogued as rs750932832, COSV64409605; called by muse, mutect2, varscan2
- IGFL3 | c.267C>T p.P89= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV58243123; called by muse, mutect2, varscan2
- KCNH3 | c.3157T>C p.L1053= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV57791989; called by muse, mutect2, varscan2
- MINK1 | c.732C>A p.L244= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100767209, COSV61791671; called by muse, mutect2, varscan2
- MYH13 | c.3831G>C p.L1277= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV52836695, COSV52844571; called by muse, mutect2, varscan2
- MYLPF | c.372G>A p.L124= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV58443066; called by muse, mutect2, varscan2
- NRXN3 | c.2577G>A p.L859= (on ENST00000335750 / NM_001330195.2; = p.L486= on NM_004796.6) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV59781572; called by muse, mutect2, varscan2
- OIP5 | c.689G>A p.*230= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV55034154; called by muse, mutect2, varscan2
- PHOSPHO1 | c.397C>T p.L133= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56800951; called by muse, mutect2, varscan2
- PLCD3 | c.423C>T p.I141= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV59561901; called by muse, mutect2
- PLIN5 | c.712C>T p.L238= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV67850895; called by muse, mutect2, varscan2
- PPP2R5C | c.1518G>A p.K506= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs751849172, COSV100159765; called by muse, varscan2
- PRDX6 | c.465G>A p.R155= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV61165981; called by muse, mutect2, varscan2
- RAB40AL | c.216G>C p.G72= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV54435248; called by muse, mutect2, varscan2
- RABL6 | c.414G>A p.K138= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100273562; called by muse, mutect2, varscan2
- ROR2 | c.169C>T p.L57= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs779047326, COSV65221964, COSV65221975; called by muse, mutect2, varscan2
- SIM2 | c.1203C>T p.C401= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs145321008; called by muse, mutect2, varscan2
- SLC30A2 | c.609C>T p.P203= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV65333106; called by muse, mutect2, varscan2
- SLC4A2 | c.2262C>T p.F754= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV52541334, COSV99034136; called by muse, mutect2, varscan2
- SMPD1 | c.348C>T p.S116= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs767122852, COSV54969613; called by muse, mutect2, varscan2
- SNCG | c.264C>T p.I88= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100813815, COSV62318318; called by muse, mutect2, varscan2
- TCTE3 | c.441C>T p.F147= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV64656058; called by muse, mutect2, varscan2
- TOM1 | c.384C>T p.F128= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV65898922; called by muse, mutect2, varscan2
- TREML2 | c.738C>T p.L246= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV72439208; called by muse, mutect2, varscan2
- TSR3 | c.417G>T p.G139= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV50104644; called by muse, mutect2, varscan2
- TUBB | c.456C>T p.I152= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV58358115; called by muse, mutect2, varscan2
- WDR45 | c.240G>A p.L80= (on ENST00000376372 / NM_001029896.2; = p.L81= on NM_007075.3) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100540332; called by muse, mutect2, varscan2
- WDR64 | c.1413C>T p.L471= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs374361180; called by muse, mutect2, varscan2
- ZBTB44 | c.1236G>A p.Q412= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs1161464398, COSV100777312; called by muse, mutect2, varscan2
- ZSWIM3 | c.1050C>G p.L350= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1318124524, COSV54849784; called by muse, mutect2, varscan2
- ZSWIM3 | c.1890C>G p.L630= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as COSV54849799; called by muse, mutect2, varscan2
- ZXDC | c.831C>T p.F277= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1340281411, COSV60447856; called by muse, mutect2, varscan2
- NAP1L3 | c.-1G>A | 5'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs766425655, COSV100220528, COSV100220700; called by muse, mutect2, varscan2
- TRIM24 | c.*996G>A | 3'UTR (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100631087; called by muse, mutect2, varscan2
- Vault | n.73G>A | RNA (SNP) | VAF 27/39 reads (69%) | called by muse, mutect2, varscan2
